Somatic mutation profile of tumor specimen TCGA-A3-3365-01A (aliquot TCGA-A3-3365-01A-01D-0966-08) from TCGA case TCGA-A3-3365, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.3 years (16,915 days).
Specimen TCGA-A3-3365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2148fa99-80a3-4ff4-9794-f3af3d2f9dcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3365-11A (Solid Tissue Normal), aliquot TCGA-A3-3365-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a3b4aea-278a-4943-805b-8e567a34c7bb

The open-access MAF lists 38 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 26, Silent 6, Frame Shift Del 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.1517A>T p.K506I | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56989478; called by muse, mutect2, varscan2
- ADGRG6 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV51592244; called by muse, mutect2, varscan2
- ANKRD42 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs760713904, COSV52615828; called by muse, mutect2, varscan2
- BAZ1B | c.4310T>C p.V1437A | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV59991122; called by muse, mutect2, varscan2
- BID | c.510C>G p.N170K (on ENST00000317361 / NM_197966.2; = p.N124K on NM_001196.4) | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV58006836; called by muse, mutect2, varscan2
- BRCA2 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.755); catalogued as COSV66453672, COSV66458383; called by muse, mutect2, varscan2
- CAMLG | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.525); catalogued as rs777356231, COSV51804724; called by muse, mutect2, varscan2
- CBLC | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV54322587, COSV54323208; called by muse, mutect2, varscan2
- COPS4 | c.210C>A p.C70* | Nonsense Mutation (SNP) | VAF 40/241 reads (17%) | catalogued as COSV52314937; called by muse, mutect2, varscan2
- CYP4A11 | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); catalogued as COSV60223501; called by muse, mutect2, varscan2
- DNAJC16 | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 59/283 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61601471; called by muse, mutect2, varscan2
- GAK | c.3834+2T>C p.X1278_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV58504697; called by muse, mutect2
- GAK | c.1004A>G p.N335S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.351); catalogued as COSV58504706; called by muse, mutect2, varscan2
- JAKMIP2 | c.1892A>C p.D631A | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54604439; called by muse, mutect2, varscan2
- JKAMP | c.199C>G p.P67A (on ENST00000554271 / NM_001284201.1; = p.P53A on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/398 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV54199466; called by muse, mutect2, varscan2
- JUP | c.1459A>C p.K487Q | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV60278007; called by muse, mutect2, varscan2
- KMT2D | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1441499895, COSV56439462; called by muse, mutect2, varscan2
- L1CAM | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV62828076; called by muse, mutect2, varscan2
- MICU1 | c.1297T>C p.F433L (on ENST00000361114 / NM_001195518.2; = p.F439L on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV63144860; called by muse, mutect2, varscan2
- PSMD6 | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV55759806; called by muse, mutect2, varscan2
- PTPN13 | c.1627T>C p.F543L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57407646; called by muse, mutect2, varscan2
- RTN4 | c.1403A>C p.N468T | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58267777; called by muse, mutect2
- SIK2 | c.1870A>C p.I624L | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59252318; called by muse, mutect2, varscan2
- SIPA1L2 | c.356G>C p.S119T | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV53390407; called by muse, mutect2, varscan2
- TASOR2 | c.5012T>G p.V1671G | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV60167451; called by muse, mutect2
- VAPB | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV55667575; called by muse, mutect2, varscan2
- ZNF292 | c.3098T>A p.V1033E | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as COSV60539414; called by muse, mutect2, varscan2
- ZNF324B | c.1608C>A p.S536R | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV60741787; called by muse, mutect2, varscan2
- BCAN | c.2253del p.I752Sfs*104 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- ITM2B | c.790_791delinsG p.I264Vfs*19 | Frame Shift Del (DEL) | VAF 22/161 reads (14%) | called by pindel, varscan2*
- NFIB | c.165_166del p.R55Sfs*5 | Frame Shift Del (DEL) | VAF 33/188 reads (18%) | called by pindel, varscan2
- PBRM1 | c.513del p.T172Qfs*2 | Frame Shift Del (DEL) | VAF 101/440 reads (23%) | called by mutect2, pindel, varscan2
- FN1 | c.6081G>T p.G2027= | Silent (SNP) | VAF 50/194 reads (26%) | catalogued as COSV60552796; called by muse, mutect2, varscan2
- KMT2D | c.786C>T p.A262= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs368315432; called by muse, mutect2, varscan2
- MICU2 | c.1209A>G p.Q403= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as rs762908813, COSV66673994; called by muse, mutect2, varscan2
- PCDHGC5 | c.744T>A p.R248= | Silent (SNP) | VAF 73/334 reads (22%) | catalogued as COSV52751764; called by muse, mutect2, varscan2
- SGCA | c.1083C>G p.P361= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV56249310; called by muse, mutect2, varscan2
- SLC9A9 | c.867G>T p.G289= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs1215314136, COSV57227117; called by muse, mutect2, varscan2
